TCGA case TCGA-06-0650 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/522808a2-f19d-4fab-b67e-0c31ec54b757

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 717 days (2.0 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 39.9 years (14,560 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 67 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 67 days; Number of cycles: 1; Treatment dose: 110 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 96 days; Days to treatment end: 355 days; Number of cycles: 4; Treatment dose: 230 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 389 days (1.1 years); Days to treatment end: 389 days (1.1 years); Number of cycles: 1; Treatment dose: 160 mg; Prescribed dose: 160; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Days to treatment start: 389 days (1.1 years); Days to treatment end: 431 days (1.2 years); Number of cycles: 1; Treatment dose: 20 mg/day; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 495 days (1.4 years); Days to treatment end: 513 days (1.4 years); Number of cycles: 1; Treatment dose: 150 mg/day; Prescribed dose: 150; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 516 days (1.4 years); Days to treatment end: 658 days (1.8 years); Treatment dose: 614 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 516 days (1.4 years); Days to treatment end: 560 days (1.5 years); Number of cycles: 2; Treatment dose: 200 mg; Prescribed dose: 125; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 564 days (1.5 years); Days to treatment end: 580 days (1.6 years); Treatment dose: 3,600 cGy; Number of fractions: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 586 days (1.6 years); Days to treatment end: 678 days (1.9 years); Number of cycles: 3; Treatment dose: 160 mg; Prescribed dose: 100; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 678 days (1.9 years); Days to treatment end: 684 days (1.9 years); Treatment dose: 2,400 cGy; Number of fractions: 3; Treatment anatomic sites: Locoregional Site.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 40.8 years (14,911 days); Days to diagnosis: 351 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 355 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 351 (post initial treatment): Progression or recurrence: Yes; Days to progression: 351 days.
- Days to follow up: 717 days (2.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0650-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-06-0650-01A-01-BS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100.
  Slide TCGA-06-0650-01A-02-BS2: Section location: Bottom; Percent tumor cells: 10; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 80.
- Sample TCGA-06-0650-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: AZD.
- Drug treatment 5, Route of administrations: Route of administration: IV.
- Radiation treatment 1: Radiation type other: Fractionated stereotactic radiotherapy; Therapy regimen other: Site of treatment was regional.
- Radiation treatment 2: Radiation type other: Stereotactic radiotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 717 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 717 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 351 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0650-01A-02D-1694-01): tumor purity 0.23, ploidy 2.03, whole-genome doublings 0.
